Surgical pathology report (de-identified scan), TCGA case TCGA-09-1662, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1662-01A (Primary Tumor).

[page 1 of 10]
[REDACTED]

[REDACTED]

[REDACTED]

Specimen(s) Received

A: Left ovary fs

[REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

B: Anterior rectal wall tumor

[REDACTED]

H&E, First x 1, H&E, First x 1

C: Anterior rectal mass

[REDACTED]

D: Omentum

[REDACTED]

H&E, First x 1, H&E, First x 1

E: Spleen

[REDACTED]

H&E, First x 1, H&E, First x 1

F: Appendix

[REDACTED]

H&E, First x 1

G: Right groin node

[REDACTED]

H&E, First x 1, H&E, First x 1

H: Retro-hepatic tumor

[REDACTED]

H&E, First x 1, H&E, First x 1

I: Umbilical nodule

[REDACTED]

H&E, First x 1, H&E, First x 1

J: Uterus and right ovary

[REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

K: Peri-aortic lymph node

[REDACTED]

H&E, First x 1

Final Pathologic Diagnosis:

A. Left ovary and fallopian tube, salpingo-oophorectomy: Poorly differentiated serous carcinoma, high grade, 6.0 cm in greatest dimension, involving the left ovary and left fallopian tube; see comment.

B. Anterior rectal wall, biopsy: Metastatic serous carcinoma.

C. "Anterior rectal mass," biopsy: Connective tissue with chronic inflammation, no

Page 1 of 10

tumor seen.

D. Omentum, omentectomy: Metastatic serous carcinoma, 16.0 cm in greatest dimension.

E. Spleen, splenectomy: Metastatic serous carcinoma.

F. Appendix, appendectomy: Appendix with no significant pathologic abnormality, no tumor seen.

G. Lymph nodes, right groin, excision: Three lymph nodes with metastatic serous carcinoma (3/5).

[page 2 of 10]
- H. "Retrohepatic tumor," excision: Metastatic serous carcinoma.
- I. "Umbilical nodule," excision: Metastatic serous carcinoma.
- J. Uterus, right ovary and right fallopian tube; hysterectomy and right salpingo-oophorectomy:
1. Uterus
- Cervix: No significant pathologic abnormality.
- Endometrium: Atrophy.
- Myometrium: Leiomyomata.
- Serosa: No significant pathologic abnormality.
2. Right ovary with metastatic serous carcinoma.
3. Fallopian tube with no significant pathologic abnormality.
- K. Lymph nodes, periaortic, excision: Five lymph nodes with no tumor seen (0/5).

Note:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Serous.
2. Grade of tumor: III (high grade).
3. Location of tumor: Unilateral, left ovary; although the right ovary shows tumor, it appears to represent a metastatic serosal implant.
4. Diameter of tumor: 6.0 cm.
5. Appearance of surface of ovary: Tumor on surface.
6. Condition of capsule: Ruptured.
7. Appearance of cut surface: Solid.
8. Color of solid areas: Tan to pink.
9. Necrosis: None present.
10. Lymphatic/vascular invasion: Lymphovascular space invasion.
11. Sites of metastases in pelvis: Left fallopian tube, right ovary and "rectal wall."
12. Pelvic lymph nodes: Three of five lymph nodes contain metastatic tumor (3/5).
13. Sites of metastases in abdomen: Omentum, spleen, retrohepatic area and umbilical area. Maximum diameter of largest abdominal metastasis = 16.0 cm.
14. Para-aortic lymph nodes: Zero of five contain metastatic tumor (0/5).
15. Peritoneal cytology: Not collected.
16. Other significant findings: None.
17. FIGO stage: IV.
18. TNM stage: pT3cN1M1.

Intraoperative Consult Diagnosis

FS1 (A) Ovary, left, oophorectomy: Serous carcinoma.

Page 2 of 10

Clinical History

The patient is a [REDACTED] who presents with a pelvic mass and undergoes left oophorectomy.

Gross Description

The specimen is received in eleven parts, labeled with the patient's name and medical record number. Parts C-K are received in formalin.

Part A, received fresh from the Operating Room and labeled "left ovary," consists of one ovary weighing 31.5

gm and measuring 6.2 x 4.1 x 2.0 cm. Attached to the ovary is a fallopian tube measuring 6.0 cm in length

x 1.0 cm in average cross-section. 2.0 cm from the end of this tube is an area where the tube expands to

[page 3 of 10]
1.5 cm. The ovary is soft, with a papillated, shaggy surface. It is pink-tan and friable. A segment is distal into the ovary and taken for research purposes, and a segment adjacent to this is frozen for intraoperative

diagnosis. The outside of the specimen is inked black. Representative sections are submitted as follows:

Cassette A1: Remnant of frozen section.

Cassette A2: Segment of ovary demonstrating tumor.

Cassette A3: Segment of tube with mass.

Cassette A4: Proximal margin of fallopian tube and representative section of normal tube.

Part B, received fresh from the Operating Room and labeled "anterior rectal wall tumor," consists of one soft, pink-red, irregular specimen of tissue measuring 9.0 x 3.5 x 0.6 cm. A segment of this tissue measuring 1.0 x 2.0 x 0.4 cm is similar in appearance to the main tumor. This segment of tissue is removed and submitted to Oncotech as per the patient's and the surgeon's directions. The specimen is serially sectioned and representative sections are submitted in cassettes [REDACTED]

Part C, labeled "anterior rectal mass," consists of a single, unoriented fragment of tan to gray, soft tissue measuring 3.0 x 2.4 x 1.2 cm. Serial sectioning reveals wrinkled, gray tissue, which appears to have intermixed white tissue, which may represent tumor. Representative sections are submitted in cassette [REDACTED]

Part D, labeled "omentum," consists of two, unoriented, irregularly shaped fragments of tan to yellow, soft

tissue, which grossly appear to be omentum completely infiltrated by metastatic tumor. The fragments measure 16.0 x 14.0 x 4.5 cm in aggregate. Representative sections are submitted in cassettes [REDACTED]

Part E, labeled "spleen," consists of a single, irregularly shaped and unoriented fragment of soft tissue measuring 12.5 x 10.0 x 5.5 cm. It consists of a red spleen, which has large areas grossly involved with tan-yellow tumor. Representative sections are submitted in cassettes [REDACTED] including junction between spleen and tumor.

Part F, labeled "appendix," consists of an appendectomy specimen measuring 3.2 x 2.5 x 0.5 cm. The appendix measures 3.3 cm in length, with an average diameter of 0.5 cm. Representative sections, including a longitudinal section of the tip, are submitted in cassettes [REDACTED] Grossly, no abnormalities are noted.

Part G, labeled "right groin node," consists of multiple, irregularly shaped fragments of tissue measuring 3.5 x 3.0 x 1.4 cm in aggregate. Two of these fragments appear to be lymph nodes, which have been entirely replaced by tumor. These lymph nodes are submitted in cassette [REDACTED] Additional lymph nodes are submitted in cassette [REDACTED]

Part H, labeled "retrohepatic tumor," consists of two, irregularly shaped fragments of tan to white, soft tissue, measuring 3.3 x 2.0 x 1.8 cm in aggregate. They grossly appear to represent the same tumor identified in prior specimens. Sections from each fragment are submitted in cassettes [REDACTED].

Part I, labeled "umbilical nodule," consists of multiple, irregularly shaped fragments of tan to gray, soft tissue measuring 2.5 x 2.5 x 1.3 cm in aggregate. These again demonstrate the same tan tumor found in other specimens in this case. Representative sections are submitted in cassettes [REDACTED]

Part J is received in formalin additionally labeled "uterus and right ovary." It consists of a uterus with attached cervix, as well as the right ovary and right fallopian tube. The uterus measures 9 cm superior to inferior, 6 cm cornu to cornu, and 4 cm anterior to posterior. The cervix has a fish-mouth os, which measures 0.4 cm. The cervix measures 2.5 cm in diameter and has a length of 1.7 cm. The right ovary measures 3 cm in length and has a maximum diameter of 2.1 cm. It is remarkable for grossly evident

Page 3 of 10

tumor on the serosal surface of the ovary. The right fallopian tube measures 5.3 cm in length and has an average diameter of 0.5 cm.

The uterus is opened to reveal unremarkable endometrium. The endometrium measures 0.1 cm in thickness. The myometrium measures 1.2 cm in thickness and contains multiple leiomyomata, the largest measuring 2.3 cm in maximum diameter. The serosal surface on the posterior side of the uterus shows a small subserosal leiomyoma, measuring 1.4 cm in maximum diameter. The uterus is oriented by the peritoneal reflection and inked black posteriorly and blue anteriorly. Sections of the uterus are submitted

[page 4 of 10]
as follows.

Cassette J1: Anterior cervix.

Cassette J2: Posterior cervix.

Cassette J3: Anterior endomyometrium.

Cassette J4: Posterior endomyometrium.

Cassette J5: Posterior uterine subserosal leiomyoma.

The tumor on the surface of the ovary measures 2.0 cm in greatest dimension. Sectioning through the ovary reveals that it appears to be involved by the tumor internally, as well as externally. The ovary additionally contains a cystic area 1.2 cm in maximal dimension. Representative sections of the ovary showing tumor invasion and tumor on the surface are submitted in cassette [REDACTED]. An additional section of the ovary showing the cystic space is submitted in cassette [REDACTED]. Grossly, the fallopian tube is not involved by tumor. Representative fallopian tube sections are submitted in cassette [REDACTED].

Part K, labeled "right peri-aortic lymph," consists of a single, irregularly shaped fragment of black, soft tissue, which appears to be lymph node. It measures 3.2 x 2.5 x 0.3 cm. The specimen is entirely submitted in cassette [REDACTED].

Other Specimens

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

Scant cellularity.

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

UNSATISFACTORY FOR EVALUATION.

See Below.

[page 5 of 10]
[REDACTED]

Unsatisfactory for evaluation due to scant cellularity.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

Page 5 of 10

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

[page 6 of 10]
Vaginal, Thin Prep Imaged
NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.
Reactive cellular changes.
Atrophic changes
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

Specimen(s) Received: Peritoneal Washing
Final Diagnosis
Peritoneal Washing
ADENOCARCINOMA, METASTATIC.

Specimen(s) Received: A: Retroperitoneal mass (FS), B: Liver biopsy (FS), C: Right diaphragm nodule #1, D: Right diaphragm nodule #2, E: Right diaphragm nodule #3, F: Nodule on cecum, G: Nodule on bladder #1, H: Nodule on bladder #2, I: Gallbladder, J: Left lobe liver

Final Diagnosis

A. Retroperitoneal mass, biopsy:

Serous adenocarcinoma consistent with metastasis from ovarian primary, infiltrating fibroadipose tissue.

B. Liver, biopsy:

Serous adenocarcinoma consistent with metastasis from ovarian primary, involving fibrous connective tissue adjacent to liver parenchyma.

C. Right diaphragm nodule #1, biopsy:

Page 6 of 10

Serous adenocarcinoma consistent with metastasis from ovarian primary, infiltrating fibrous connective tissue.

D. Right diaphragm nodule #2, biopsy:

Serous adenocarcinoma consistent with metastasis from ovarian primary, infiltrating fibrous connective tissue adjacent to skeletal muscle.

E. Right diaphragm nodule #3, biopsy:

Serous adenocarcinoma consistent with metastasis from ovarian primary, infiltrating fibrous connective tissue and skeletal muscle.

F. Nodule on cecum, biopsy:

[page 7 of 10]
[REDACTED]

Benign dense fibrous connective tissue; no tumor identified. [REDACTED]

G. Nodule on bladder, #1, biopsy:

Serous adenocarcinoma consistent with metastasis from ovarian primary, infiltrating fibrous connective tissue.

H. Nodule on bladder, #2, biopsy:

Benign fibrous nodule and suture material with associated foreign giant-cell reaction; no tumor identified.

I. Gallbladder, cholecystectomy:

1. Gallbladder with no significant pathologic abnormalities.

2. Cystic duct lymph node with no significant pathologic abnormalities.

3. No tumor identified.

J. Liver, left lobe, lobectomy:

1. Serous adenocarcinoma consistent with metastasis from ovarian primary, 2.5 cm in greatest dimension, infiltrating hepatic parenchyma and hepatic hilar tissue.

2. No tumor identified at surgical resection margins.

3. Non-neoplastic liver shows no significant pathologic abnormalities.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

[page 8 of 10]
[REDACTED]

Specimen(s) Received: Left Inguinal Lymph Node, Fine Needle Aspiration

Final Diagnosis

Left Inguinal Lymph Node, Fine Needle Aspiration: Reactive lymph node. See note.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

Page 8 of 10

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

[page 9 of 10]
[REDACTED]

Vaginal, Thin Prep
NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.
Inflammation.
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep
Final Diagnosis
Vaginal, Thin Prep
CELLULAR CHANGES WITHIN NORMAL LIMITS.
Inflammation.
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vagina, biopsy
Final Diagnosis
Vagina, biopsy: Lamina propria fibrosis; see comment.
Page 9 of 10

[REDACTED]

[REDACTED]

Specimen(s) Received: Cervical, Thin Prep
Final Diagnosis
Cervical, Thin Prep
CELLULAR CHANGES WITHIN NORMAL LIMITS.
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep
Final Diagnosis
Vaginal, Thin Prep
BENIGN CELLULAR CHANGES.

[page 10 of 10]
[REDACTED]

Reactive changes:

Squamous metaplasia.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Urine, catheterized

Final Diagnosis

Urine, catheterized

BENIGN.

[REDACTED]

Source: NCI Genomic Data Commons file b535a948-f62a-48d6-a224-1d308cc87c2a (TCGA-09-1662.8E2676A4-2AC3-42AF-BE7D-CF74B6D82F2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).